Somatic mutation profile of tumor specimen TCGA-04-1361-01A (aliquot TCGA-04-1361-01A-01W-0494-09) from TCGA case TCGA-04-1361, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 57.1 years (20,860 days).
Specimen TCGA-04-1361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e990a34-2e59-459f-9d75-60f257fc4fd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1361-11A (Solid Tissue Normal), aliquot TCGA-04-1361-11A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/530df1f0-f586-4c01-bd62-5876f7dbf973

The open-access MAF lists 75 somatic variants for this specimen: 59 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 15, Splice Site 4, Nonsense Mutation 2, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 42/57 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC008397.2 | c.1370T>C p.L457P | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53206649; called by muse, mutect2, varscan2
- ACSL1 | c.1832G>A p.W611* | Nonsense Mutation (SNP) | VAF 95/283 reads (34%) | catalogued as COSV55662274; called by muse, mutect2, varscan2
- ADGRV1 | c.11923G>C p.E3975Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV67984018; called by muse, mutect2, varscan2
- ADORA3 | c.239T>A p.F80Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV53985681; called by muse, mutect2, varscan2
- AKAP6 | c.1666C>A p.P556T | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99797271, COSV99799764; called by muse, mutect2
- AP1G2 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs146088258; called by muse, mutect2, varscan2
- ATRX | c.3316G>T p.D1106Y | Missense Mutation (SNP) | VAF 105/461 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV100970443; called by muse, mutect2, varscan2
- BNC1 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100597054; called by muse, mutect2
- BPIFA2 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs760819132, COSV53610915; called by muse, mutect2, varscan2
- CHST9 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1291133808, COSV52432602, COSV52444029; called by muse, mutect2
- CLASP2 | c.4421A>T p.D1474V (on ENST00000359576; = p.D1473V on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV56281242; called by muse, mutect2, varscan2
- CNTNAP5 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs890816163, COSV70496411, COSV70507161; called by muse, mutect2
- CSMD3 | c.7802G>T p.R2601L (on ENST00000297405 / NM_001363185.1; = p.R2497L on NM_052900.3) | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV52100352, COSV52124954; called by muse, varscan2
- DEPDC5 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV56696381; called by muse, mutect2, varscan2
- DNAH8 | c.13361A>T p.K4454M | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59441755; called by muse, mutect2, varscan2
- DNMT3A | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV53049784, COSV53062545; called by muse, mutect2, varscan2
- EIF3L | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV67739555; called by muse, mutect2, varscan2
- EPS15L1 | c.2458G>C p.D820H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV50168390; called by muse, mutect2, varscan2
- EVI5 | c.2308C>A p.P770T | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.047); catalogued as COSV64826752; called by muse, mutect2, varscan2
- FAM20B | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as rs1311580518, COSV55380029; called by muse, mutect2, varscan2
- FAM91A1 | c.1639C>G p.P547A | Missense Mutation (SNP) | VAF 110/788 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100593876, COSV58236826; called by muse, mutect2, varscan2
- GNPDA2 | c.376A>T p.K126* | Nonsense Mutation (SNP) | VAF 62/184 reads (34%) | catalogued as COSV54946524; called by muse, mutect2, varscan2
- ITPR2 | c.7000A>C p.T2334P | Missense Mutation (SNP) | VAF 62/107 reads (58%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); catalogued as COSV67268575; called by muse, mutect2, varscan2
- KIAA1210 | c.985T>A p.L329M | Missense Mutation (SNP) | VAF 118/322 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.923); catalogued as COSV68176885; called by muse, mutect2, varscan2
- LIG4 | c.2037G>T p.E679D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100799793, COSV63597405; called by muse, mutect2, varscan2
- LVRN | c.1516-1G>C p.X506_splice | Splice Site (SNP) | VAF 32/102 reads (31%) | catalogued as COSV100773313, COSV63497106; called by muse, mutect2, varscan2
- MAP1A | c.3830C>A p.T1277K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV100288390; called by muse, mutect2, varscan2
- MOGAT2 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52219116; called by muse, mutect2
- MOGAT2 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as rs773320617, COSV52219126, COSV52221313; called by muse, mutect2, varscan2
- MYH11 | c.2652+2T>A p.X884_splice | Splice Site (SNP) | VAF 75/212 reads (35%) | catalogued as COSV55551266; called by muse, mutect2, varscan2
- MYO18A | c.5245G>C p.E1749Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62865759; called by muse, mutect2, varscan2
- NLRP13 | c.3081G>T p.M1027I | Missense Mutation (SNP) | VAF 224/668 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV61621417; called by muse, mutect2, varscan2
- NUP93 | c.1261G>T p.V421L | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.166); catalogued as COSV57430526; called by muse, mutect2, varscan2
- OMD | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65020147; called by muse, mutect2, varscan2
- PCDHGC5 | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.577); catalogued as COSV52750232; called by muse, mutect2, varscan2
- PDIA5 | c.1347T>A p.I449= | Splice Region (SNP) | VAF 43/118 reads (36%) | catalogued as COSV60248836; called by muse, mutect2, varscan2
- PPIG | c.1579A>G p.S527G | Missense Mutation (SNP) | VAF 139/277 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.027); catalogued as COSV53642700; called by muse, mutect2, varscan2
- PRPH2 | c.54A>T p.Q18H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs752955075, COSV57837065; called by muse, mutect2, varscan2
- PSAP | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV67550243; called by muse, mutect2, varscan2
- PTGS2 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV66569060; called by muse, mutect2, varscan2
- RDH8 | c.320T>A p.L107Q (on ENST00000651512; = p.L87Q on NM_015725.4) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50674758; called by muse, mutect2, varscan2
- RIMS1 | c.206C>G p.T69R | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53449380, COSV53452915; called by muse, mutect2, varscan2
- SCN1A | c.4581+1G>A p.X1527_splice (on ENST00000303395 / NM_001202435.3; = p.X1516_splice on NM_006920.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 35/136 reads (26%) | catalogued as CS096250, CS1211444, COSV57668357; called by muse, mutect2, varscan2
- SETD5 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs775518851, COSV56710308; called by muse, mutect2, varscan2
- SLC12A2 | c.1969T>G p.L657V | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52470784; called by muse, mutect2
- SORCS1 | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs143280827, COSV99544965; called by muse, mutect2, varscan2
- SULT1C2 | c.473A>G p.E158G | Missense Mutation (SNP) | VAF 130/262 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV52264708; called by muse, mutect2, varscan2
- TRAPPC10 | c.68G>A p.C23Y | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs909080917, COSV52377041; called by muse, mutect2, varscan2
- TXLNA | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV65314254; called by muse, mutect2, varscan2
- VTI1A | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV67580037; called by muse, varscan2
- XPC | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.054); catalogued as COSV53204715; called by muse, mutect2, varscan2
- ZNF304 | c.649T>C p.Y217H | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56584100; called by muse, mutect2, varscan2
- ASF1B | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- CD244 | c.1033-35_1036del p.X345_splice (on ENST00000368033 / NM_001166663.2; = p.X340_splice on NM_016382.4) | Splice Site (DEL) | VAF 62/256 reads (24%) | called by mutect2, pindel
- CPB1 | c.606_612dup p.E205Sfs*19 | Frame Shift Ins (INS) | VAF 13/88 reads (15%) | called by mutect2, varscan2
- IGHV1-58 | c.56_68del p.S19Wfs*8 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel
- TSPYL5 | c.518_535del p.A173_S178del | In Frame Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- ZNF765 | c.499_511del p.S167Lfs*27 | Frame Shift Del (DEL) | VAF 26/268 reads (10%) | called by mutect2, pindel
- ABCB4 | c.3636G>A p.L1212= (on ENST00000265723 / NM_018849.3; = p.L1205= on NM_000443.4) | Silent (SNP) | VAF 112/287 reads (39%) | catalogued as COSV55934593; called by muse, mutect2, varscan2
- AIFM1 | c.1464C>A p.P488= | Silent (SNP) | VAF 89/328 reads (27%) | catalogued as COSV54854254, COSV54855797; called by muse, mutect2, varscan2
- C20orf194 | c.2076G>T p.R692= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- CACNA1F | c.2790G>A p.L930= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- CD207 | c.672G>A p.V224= | Silent (SNP) | VAF 29/209 reads (14%) | catalogued as rs372167399; called by muse, mutect2, varscan2
- DNAH3 | c.4179T>C p.Y1393= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as COSV54518296; called by muse, mutect2, varscan2
- EVC | c.582G>T p.R194= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs200101865, COSV53832072; called by muse, mutect2, varscan2
- GSDME | c.324C>T p.R108= | Silent (SNP) | VAF 102/161 reads (63%) | catalogued as rs376703607; called by muse, mutect2, varscan2
- NPAT | c.3552A>G p.S1184= | Silent (SNP) | VAF 94/445 reads (21%) | catalogued as rs763374237, COSV53717770; called by muse, mutect2, varscan2
- OR4E2 | c.903C>G p.L301= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV57731672, COSV57732198; called by muse, mutect2, varscan2
- POGLUT1 | c.573G>A p.L191= | Silent (SNP) | VAF 10/262 reads (4%) | catalogued as COSV99809520; called by muse, mutect2
- POLQ | c.4377A>T p.I1459= | Silent (SNP) | VAF 128/238 reads (54%) | catalogued as COSV51750461; called by muse, mutect2, varscan2
- STK26 | c.1143C>T p.L381= | Silent (SNP) | VAF 81/291 reads (28%) | catalogued as rs34419165, COSV53745806; called by muse, mutect2, varscan2
- UBE3C | c.2508G>A p.E836= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV61952811; called by muse, mutect2, varscan2
- ZNF180 | c.1167C>A p.S389= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV55419655; called by muse, mutect2
- CPLANE1 | c.*5636C>A | 3'UTR (SNP) | VAF 73/237 reads (31%) | catalogued as COSV57058563; called by muse, mutect2, varscan2
